Somatic mutation profile of tumor specimen TCGA-F5-6464-01A (aliquot TCGA-F5-6464-01A-11D-1733-10) from TCGA case TCGA-F5-6464, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 77.1 years (28,168 days).
Specimen TCGA-F5-6464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4202a57e-31b9-4207-9e07-41d89810ea4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F5-6464-10A (Blood Derived Normal), aliquot TCGA-F5-6464-10A-01D-1733-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7bff274-fd24-4560-9809-6596e87d10d4

The open-access MAF lists 92 somatic variants for this specimen: 78 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 68, Silent 14, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- SMAD4 | c.1088_1090del p.C363del | In Frame Del (DEL) | VAF 47/105 reads (45%) | hotspot (GDC flag); catalogued as rs377767349; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.5035T>G p.L1679V (on ENST00000272895 / NM_173076.3; = p.L1361V on NM_015657.3) | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as COSV55980049; called by muse, mutect2, varscan2
- ADAMTS16 | c.1729T>C p.Y577H | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV99939834; called by muse, mutect2, varscan2
- ADAMTS20 | c.3866A>C p.Q1289P | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV67141441; called by muse, mutect2, varscan2
- ADGRL2 | c.3551A>G p.N1184S | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.088); catalogued as COSV54694439; called by muse, mutect2, varscan2
- AHCY | c.1262G>A p.C421Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV54154748; called by muse, mutect2, varscan2
- ANKRD50 | c.1970A>T p.E657V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV72386451; called by muse, mutect2, varscan2
- AVIL | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs192714655, COSV99142140; called by muse, mutect2, varscan2
- C1orf141 | c.962T>C p.F321S | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV100924267; called by muse, mutect2, varscan2
- C2CD2L | c.453G>T p.V151= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as COSV60885058; called by mutect2, varscan2
- C5 | c.827A>C p.K276T | Missense Mutation (SNP) | VAF 39/606 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs1554724387, COSV99797014; called by muse, mutect2
- CNR1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.028); catalogued as rs143463104; called by muse, mutect2, varscan2
- CXADR | c.1091T>C p.I364T | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV53031854; called by muse, mutect2, varscan2
- DCSTAMP | c.503A>C p.N168T | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV99886017; called by muse, mutect2, varscan2
- DLG2 | c.192T>G p.I64M | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1247938717, COSV65884465; called by muse, mutect2, varscan2
- EPHA5 | c.2442C>A p.C814* | Nonsense Mutation (SNP) | VAF 25/98 reads (26%) | catalogued as COSV99895702; called by muse, mutect2, varscan2
- FBXW10 | c.1891G>C p.A631P | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs371753550, COSV57323347; called by muse, mutect2, varscan2
- FGD6 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377183623; called by mutect2, varscan2
- GRIK2 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59745590, COSV59780905; called by muse, mutect2, varscan2
- HS3ST4 | c.1347G>A p.W449* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV58806970; called by muse, mutect2, varscan2
- HSPG2 | c.12644C>T p.P4215L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60829927; called by muse, mutect2, varscan2
- HTR5A | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs371458123; called by muse, mutect2, varscan2
- INCENP | c.544C>G p.H182D | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV53922140; called by muse, mutect2, varscan2
- ISM1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 50/107 reads (47%) | catalogued as rs1222075671, COSV99339500; called by muse, varscan2
- KCNH7 | c.2240G>T p.R747L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV59817658; called by muse, mutect2, varscan2
- KDM4B | c.3125C>T p.T1042M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs200961372, COSV50212279; called by muse, mutect2
- KLHL13 | c.1309A>C p.S437R | Missense Mutation (SNP) | VAF 86/341 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV53254303; called by muse, mutect2, varscan2
- KRI1 | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779884083, COSV57266141; called by muse, mutect2, varscan2
- LHX8 | c.136T>C p.S46P | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99633003; called by muse, mutect2, varscan2
- LRRTM4 | c.980A>C p.K327T | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.663); catalogued as COSV69143187; called by muse, mutect2, varscan2
- MAP2 | c.4002A>C p.E1334D | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.028); catalogued as COSV52312235; called by muse, mutect2, varscan2
- MAP7D3 | c.1441A>C p.I481L | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100286116; called by muse, mutect2, varscan2
- MDH1B | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs112729308; called by muse, mutect2, varscan2
- MGAT5B | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs62080221, COSV56938337; called by muse, mutect2, varscan2
- MMP16 | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV99685732; called by muse, varscan2
- MTMR8 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs777686067, COSV66393270; called by muse, mutect2, varscan2
- NAP1L3 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59078151; called by muse, mutect2, varscan2
- NCAM1 | c.1814C>T p.T605M (on ENST00000316851 / NM_181351.5; = p.T595M on NM_000615.7) | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782353037, COSV57517108; called by muse, mutect2, varscan2
- NDRG4 | c.983G>A p.R328H (on ENST00000570248 / NM_001378344.1; = p.R347H on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1366823690, COSV99261623; called by muse, mutect2, varscan2
- OGDH | c.2856G>T p.E952D | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56058514; called by muse, mutect2, varscan2
- OR4C13 | c.61A>C p.M21L | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV73648984; called by muse, mutect2, varscan2
- OR4C13 | c.377A>C p.K126T | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.314); catalogued as COSV73648985; called by muse, mutect2, varscan2
- OTC | c.37G>C p.A13P | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50005207; called by muse, mutect2, varscan2
- OTULIN | c.550C>A p.L184M | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV52507587; called by muse, mutect2, varscan2
- PDE3A | c.1211A>C p.N404T | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.025); catalogued as COSV62984825; called by muse, mutect2, varscan2
- PDE7A | c.247G>A p.G83S (on ENST00000401827 / NM_001242318.3; = p.G57S on NM_002603.4) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as COSV65154771; called by muse, mutect2, varscan2
- POLD1 | c.2632A>G p.I878V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV54533059; called by muse, mutect2, varscan2
- PPP3R1 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 105/244 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV52249948; called by muse, mutect2, varscan2
- PRMT2 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV52456320; called by muse, mutect2, varscan2
- RYR1 | c.14468C>T p.T4823M | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs148540135, CM083554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- S100A7 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.78); catalogued as COSV64193719; called by muse, mutect2
- SFTPB | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60894766; called by muse, mutect2, varscan2
- SPOCK3 | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV62740406; called by muse, mutect2
- STIP1 | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV54179580, COSV99656249; called by muse, mutect2, varscan2
- STYXL2 | c.3074C>T p.T1025M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs186762234, COSV99608497; called by muse, mutect2, varscan2
- SYNE1 | c.19027G>A p.V6343M (on ENST00000367255 / NM_182961.4; = p.V6272M on NM_033071.3) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as rs773713870, COSV55095391, COSV99551519; called by muse, mutect2, varscan2
- TAF7L | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as COSV61258192; called by muse, mutect2, varscan2
- TEKT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139532367; called by muse, mutect2, varscan2
- TP63 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1225645471, COSV53204576; called by muse, mutect2, varscan2
- TPD52L1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs774952793, COSV59191726; called by muse, mutect2, varscan2
- TTN | c.22551A>C p.E7517D (on ENST00000591111; = p.E6590D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/161 reads (21%) | PolyPhen benign (0); catalogued as COSV60416470; called by muse, mutect2, varscan2
- TTN | c.19489T>G p.F6497V (on ENST00000591111; = p.F5570V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/193 reads (14%) | PolyPhen benign (0.02); catalogued as rs1371961339, COSV100592117, COSV59896316; called by muse, mutect2, varscan2
- ULK4 | c.3401A>C p.K1134T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as COSV57226244; called by muse, mutect2
- UNC13B | c.1023C>G p.H341Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV65939683; called by muse, mutect2, varscan2
- USP40 | c.2948T>G p.L983R | Missense Mutation (SNP) | VAF 75/205 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52490137; called by muse, mutect2, varscan2
- WWC3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs1183508035, COSV66503024; called by muse, mutect2, varscan2
- XKRX | c.463G>C p.G155R | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60709595; called by muse, mutect2, varscan2
- ZFPM2 | c.1877T>A p.I626N | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.172); catalogued as COSV65876545, COSV65876562; called by muse, mutect2, varscan2
- ZNF521 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs114072043, COSV64133102; called by muse, mutect2, varscan2
- ZNF559 | c.991G>A p.G331R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV57837928; called by muse, mutect2, varscan2
- ZNF618 | c.843C>A p.I281= (on ENST00000374126 / NM_001318042.2; = p.I269= on NM_133374.2) | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as COSV55932108; called by muse, mutect2, varscan2
- ZNF91 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as COSV56095328; called by muse, mutect2, varscan2
- BTK | c.1702G>T p.V568F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCL11 | c.4_6del p.K2? | Translation Start Site (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- KLHL31 | c.1295_1297delinsAG p.S432Kfs*39 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by pindel, varscan2*
- UBQLN2 | c.1419dup p.P474Sfs*71 | Frame Shift Ins (INS) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.3486C>T p.S1162= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV60097075; called by muse, mutect2, varscan2
- BLNK | c.450C>A p.T150= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV56415995; called by muse, mutect2, varscan2
- C2CD2L | c.454C>T p.L152= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1162246181, COSV60885066; called by muse, mutect2, varscan2
- CDR1 | c.210G>A p.S70= | Silent (SNP) | VAF 182/444 reads (41%) | catalogued as rs191541717, COSV100983402, COSV65164850; called by muse, mutect2, varscan2
- CPAMD8 | c.681C>T p.H227= (on ENST00000651564; = p.H180= on NM_015692.5) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV52241527; called by muse, mutect2
- FAM234B | c.111G>A p.L37= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV52198287; called by muse, mutect2, varscan2
- HDGFL3 | c.246C>T p.N82= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs145113533; called by muse, mutect2, varscan2
- LYRM7 | c.96C>A p.A32= | Silent (SNP) | VAF 22/374 reads (6%) | catalogued as COSV101041537; called by muse, mutect2
- OR2G2 | c.90A>G p.L30= | Silent (SNP) | VAF 94/594 reads (16%) | catalogued as COSV60742702; called by muse, mutect2, varscan2
- PABPC1L | c.1821A>T p.A607= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV53843714; called by muse, mutect2, varscan2
- PCDHA11 | c.2142G>T p.L714= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV56554865; called by muse, mutect2, varscan2
- SALL1 | c.730C>T p.L244= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV51765722; called by muse, mutect2, varscan2
- TCTN1 | c.237C>T p.V79= | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV66542909; called by muse, mutect2, varscan2
- WNK3 | c.4731T>G p.T1577= | Silent (SNP) | VAF 62/381 reads (16%) | catalogued as COSV63616361; called by muse, mutect2, varscan2
